Somatic mutation profile of tumor specimen TARGET-10-PANSHK-09A (aliquot TARGET-10-PANSHK-09A-01D) from TARGET case TARGET-10-PANSHK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (837 days).
Specimen TARGET-10-PANSHK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42a140e9-014c-4063-a974-67b923d3c5c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANSHK-10A (Blood Derived Normal), aliquot TARGET-10-PANSHK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8c02105-f503-4c92-9587-92f35866668b

The open-access MAF lists 70 somatic variants for this specimen: 43 protein-altering or splice-affecting, 19 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 19, Nonsense Mutation 5, Intron 4, Splice Site 2, 5'UTR 1, RNA 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID4B | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 11/92 reads (12%) | catalogued as COSV51608682, COSV99936575; called by muse, mutect2, varscan2
- CALR3 | c.843G>C p.K281N | Missense Mutation (SNP) | VAF 17/255 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV54169678; called by muse, mutect2
- CHMP6 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs946123498, COSV57327213; called by muse, mutect2, varscan2
- COL12A1 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.169); catalogued as COSV59403847; called by muse, mutect2, varscan2
- DDX46 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV62799158; called by muse, mutect2
- DST | c.8798C>T p.S2933L | Missense Mutation (SNP) | VAF 12/221 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.656); catalogued as rs1331685805; called by muse, mutect2
- ELFN2 | c.1517G>T p.R506L | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68744241; called by muse, mutect2
- GOLGB1 | c.7531G>A p.E2511K | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100510821, COSV61469198; called by muse, mutect2, varscan2
- HUWE1 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as COSV53359922; called by muse, mutect2, varscan2
- KIRREL2 | c.667C>A p.L223M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52876473; called by muse, mutect2
- LAMC2 | c.3058G>A p.E1020K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV51457247; called by muse, mutect2
- MC4R | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 41/230 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs13447332, CM121075, CM990834, COSV55352467; called by muse, mutect2, varscan2
- PAG1 | c.814C>T p.Q272* | Nonsense Mutation (SNP) | VAF 9/103 reads (9%) | catalogued as COSV55060656; called by muse, mutect2
- PLK4 | c.1650C>A p.H550Q | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV54638442; called by muse, mutect2
- PPP2R2D | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV70779581; called by muse, mutect2, varscan2
- PRPF6 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as COSV53875944; called by muse, mutect2, varscan2
- RFT1 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as COSV56249871; called by muse, mutect2, varscan2
- SCIN | c.1664G>C p.G555A (on ENST00000297029 / NM_001112706.3; = p.G308A on NM_033128.3) | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51698758; called by muse, mutect2, varscan2
- SCN10A | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs201955990; ClinVar: uncertain significance / likely benign; called by mutect2, varscan2
- SETD1A | c.3748G>C p.E1250Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.543); catalogued as COSV52691070; called by muse, varscan2
- SLC46A2 | c.1130-1G>T p.X377_splice | Splice Site (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100953529; called by muse, mutect2
- SRGAP1 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as rs1395401551; called by muse, mutect2, varscan2
- TBC1D8 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs868408568; called by muse, mutect2, varscan2
- UBR4 | c.4865C>G p.S1622* | Nonsense Mutation (SNP) | VAF 19/111 reads (17%) | catalogued as COSV64396013; called by muse, mutect2, varscan2
- ZNF566 | c.1055C>G p.S352* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV67573425; called by muse, mutect2, varscan2
- AIRE | c.1421C>T p.S474F | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATM | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.169); called by muse, mutect2
- ATP8A2 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BNC2 | c.1115C>G p.S372C | Missense Mutation (SNP) | VAF 13/392 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- CCSER2 | c.707C>A p.S236* | Nonsense Mutation (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- CLEC2A | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2
- COG8 | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- DOCK9 | c.582+1G>T p.X194_splice (on ENST00000376460 / NM_001366676.2; = p.X195_splice on NM_015296.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- NRROS | c.1193C>A p.A398D | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.09); called by muse, mutect2
- PATL2 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- PIK3CA | c.2008C>A p.H670N | Missense Mutation (SNP) | VAF 4/81 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.435); called by muse, mutect2
- RNF113A | c.785G>T p.C262F | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RNF32 | c.406C>A p.L136I | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.175); called by muse, mutect2
- SLC35G5 | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.058); called by muse, mutect2
- TGM7 | c.1123G>T p.G375C | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- USP15 | c.1975G>A p.D659N (on ENST00000280377 / NM_001351159.2; = p.D630N on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- WDR7 | c.4441C>A p.H1481N | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.475); called by muse, mutect2
- ZSWIM3 | c.1500G>C p.Q500H | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- A4GALT | c.438G>T p.L146= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs1215596299; called by muse, mutect2
- ADGRB3 | c.981C>T p.S327= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs1033505820, COSV65386694, COSV65395370; called by muse, mutect2, varscan2
- AMOTL1 | c.1236G>A p.P412= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as rs756448740, COSV58568591; called by muse, mutect2, varscan2
- BSND | c.123C>A p.G41= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- CCN1 | c.165C>G p.V55= | Silent (SNP) | VAF 7/71 reads (10%) | called by muse, mutect2, varscan2
- CMYA5 | c.9825G>A p.P3275= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as rs1025088693; called by muse, mutect2, varscan2
- CSMD3 | c.418C>T p.L140= | Silent (SNP) | VAF 28/148 reads (19%) | called by muse, mutect2, varscan2
- EPHB2 | c.2940G>A p.Q980= (on ENST00000400191 / NM_001309193.2; = p.Q981= on NM_004442.7) | Silent (SNP) | VAF 33/174 reads (19%) | called by muse, mutect2, varscan2
- FKBP15 | c.1524C>T p.L508= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as COSV53037595, COSV53038069; called by muse, varscan2
- FSIP2 | c.19149T>C p.S6383= | Silent (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- GPR155 | c.924G>A p.V308= | Silent (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2, varscan2
- GRIN2B | c.10A>C p.R4= | Silent (SNP) | VAF 31/197 reads (16%) | catalogued as COSV74207229; called by muse, mutect2, varscan2
- MDN1 | c.5235G>A p.L1745= | Silent (SNP) | VAF 43/167 reads (26%) | called by muse, mutect2, varscan2
- PARVB | c.975G>A p.L325= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100114386; called by muse, mutect2
- SAT2 | c.402G>A p.Q134= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as rs1391365115; called by muse, mutect2
- TMEM14A | c.207G>C p.V69= | Silent (SNP) | VAF 23/110 reads (21%) | called by muse, mutect2, varscan2
- USP21 | c.1215C>T p.P405= | Silent (SNP) | VAF 19/73 reads (26%) | called by muse, mutect2, varscan2
- ZKSCAN7 | c.1614C>G p.L538= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV99837586; called by muse, mutect2, varscan2
- ZNF514 | c.54G>A p.L18= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV99728111; called by muse, mutect2, varscan2
- C3 | c.4850+28G>A | Intron (SNP) | VAF 31/120 reads (26%) | called by muse, mutect2, varscan2
- DST | c.4297-4232C>T | Intron (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2
- GPR89B | c.728-534C>G | Intron (SNP) | VAF 14/108 reads (13%) | called by muse, mutect2, varscan2
- LRRTM4 | c.-120T>C | 5'UTR (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2
- MPV17L2 | c.*118C>T | 3'UTR (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- NDUFV1 | chr11:67604409 G>C | 5'Flank (SNP) | VAF 13/69 reads (19%) | catalogued as rs748879857; called by muse, mutect2, varscan2
- SPTAN1 | c.4891-40C>A | Intron (SNP) | VAF 24/148 reads (16%) | called by muse, mutect2, varscan2
- ZNF658B | n.1983G>C | RNA (SNP) | VAF 41/172 reads (24%) | called by muse, mutect2, varscan2
